Surgical pathology report (de-identified scan), TCGA case TCGA-55-8205, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8205-01A (Primary Tumor).

Sex: Female
D.O.B.:
MRN #
Ref Physician

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Lung, right lower lobe, lobectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Histologic grade: Grade III (poorly differentiated).
3. Tumor site: Subpleural.
4. Tumor focality: Unifocal.
5. Tumor size: 6.5 x 5.7 x 4.5 cm.
6. Visceral pleural invasion: Not identified.
7. Lymphovascular space invasion: Not identified.
8. Tumor extension: Not applicable.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 2.5 cm.
2. Tumor distance from pleural surface: 0.3 cm.

Lymph Node Status (includes part B):

1. Total number of lymph nodes received: 8.
2. Total number of lymph nodes containing metastatic carcinoma: 0 (0/8).

Other:

1. Other significant findings: An area of central scarring is present in the malignancy. Additional lymph nodes were previously biopsied, and negative.
2. pTNM stage: pT2b, N0.

B. Lymph node, level 8, excision: Negative for malignancy, one node.

Electronic Signature:

COMMENTS:

The histologic appearance is identical to that in a prior biopsy which was immunohistochemically identified as a poorly differentiated adenocarcinoma. A mutation cascade study was performed on that biopsy, and will not be repeated.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: year old female with lung cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right lower lobe
- B. Level 8 lymph node

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two containers labeled with the patient's name,

Container A is received with formalin additionally labeled "right lower lobe" and contains a 17.0 x 12.0 x 5.0 cm, purple-gray, anthracotic lung lobe. A 1.5 cm in length by 1.5 cm in diameter segment of exposed bronchus is identified along with multiple segments of exposed vasculature. The endobronchial mucosa is pink-tan, glistening and wrinkled with no discrete lesions identified. Also present are multiple gray-black anthracotic nodules consistent with lymph nodes. These are up to 1.0 cm in greatest dimension. The pleura is remarkable for a 6.0 x 4.5 x 1.4 cm area of umbilication. This area is inked. The specimen is sectioned to reveal a 6.5 x 5.7 x 4.5 cm, gray-white mass that abuts the inked pleura at the site of umbilication and approaches to

within 2.5 cm of the bronchial margin which is grossly uninvolved. This tumor abuts adjacent bronchi and vasculature however discrete invasion into these entities are not identified. The uninvolved parenchyma is pink-tan and spongy. No additional lesions are identified. Representative sections are submitted in cassettes A1-7 labeled designated as follows: 1 bronchial and vascular margins, en face; 2 multiple whole lymph nodes; 3 mass to inked pleura at site of umbilication, perpendicular; 4-5 mass to vasculature; 6 mass to normal; 7 most normal appearing parenchyma. Additionally, a yellow-green and blue cassette are submitted for genomics research, each labeled

Container B is additionally labeled "level 8 lymph node" and contains a 1.0 x 0.7 x 0.5 cm, purple-gray, glistening soft tissue received in saline. The specimen is bisected and entirely submitted in cassette B labeled

Source: NCI Genomic Data Commons file 54371a8d-878b-46a3-be63-19f5ebd37b61 (TCGA-55-8205.7A632C9D-4215-4D85-83DF-30CE645D4E0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).